Somatic mutation profile of tumor specimen TCGA-IF-A4AK-01A (aliquot TCGA-IF-A4AK-01A-21D-A24N-09) from TCGA case TCGA-IF-A4AK, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 82.5 years (30,141 days).
Specimen TCGA-IF-A4AK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00799513-0fba-4819-a42a-602590a64645.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IF-A4AK-11A (Solid Tissue Normal), aliquot TCGA-IF-A4AK-11A-11D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0be78583-5346-4ee4-81e0-afe987d163dc

The open-access MAF lists 29 somatic variants for this specimen: 25 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 2, Splice Site 1, Frame Shift Del 1, RNA 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS17 | c.1086C>A p.Y362* | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | catalogued as COSV99170761; called by muse, mutect2, varscan2
- ADRA1A | c.1332C>G p.D444E | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99371188; called by muse, mutect2
- AZIN2 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745840314, COSV53858928; called by muse, mutect2, varscan2
- CCDC186 | c.20T>C p.I7T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV100991021; called by muse, mutect2, varscan2
- CTNNA2 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1468771318, COSV63570647, COSV63578276; called by muse, mutect2, varscan2
- CTNND1 | c.2134C>G p.L712V (on ENST00000399050 / NM_001085458.2; = p.L706V on NM_001331.3) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100650139; called by muse, mutect2, varscan2
- CYP2C9 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs367826293, CM155864; called by muse, mutect2, varscan2
- ELF3 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); catalogued as rs1184837452, COSV100668797; called by muse, mutect2, varscan2
- GBA3 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs565050674, COSV101545525; called by muse, mutect2, varscan2
- HS3ST6 | c.519C>A p.D173E | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99562730; called by muse, mutect2, varscan2
- ITPR2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs377464722; called by muse, mutect2, varscan2
- OPN5 | c.441G>T p.K147N | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV55245431, COSV99789857; called by muse, mutect2, varscan2
- OR14C36 | c.698C>A p.T233K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100507437, COSV58602333; called by muse, mutect2
- PADI1 | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as COSV100969133; called by muse, mutect2, varscan2
- PCDHB7 | c.626G>A p.S209N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.022); catalogued as rs868986357, COSV50755744; called by muse, mutect2
- PDHA2 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54777893, COSV99756943; called by muse, mutect2, varscan2
- PTPRS | c.3725A>G p.Y1242C | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99509618; called by muse, mutect2, varscan2
- SFSWAP | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1179523909, COSV55520814, COSV99906145; called by muse, mutect2, varscan2
- SNED1 | c.3050C>T p.T1017M | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV60025957; called by muse, mutect2, varscan2
- TINAG | c.1286A>G p.E429G | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.966); catalogued as COSV99449728; called by muse, mutect2, varscan2
- UBE2E3 | c.199C>G p.Q67E | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV101150410; called by muse, mutect2
- VASP | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs371283026; called by muse, mutect2, varscan2
- VAV3 | c.1259+2T>C p.X420_splice | Splice Site (SNP) | VAF 22/40 reads (55%) | catalogued as COSV100579874; called by muse, mutect2, varscan2
- MDN1 | c.2555del p.L852Cfs*32 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- TNKS2 | c.2573G>T p.S858I | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- NIPAL3 | c.477C>T p.H159= | Silent (SNP) | VAF 35/44 reads (80%) | catalogued as rs759916543, COSV50232227; called by muse, mutect2, varscan2
- STIP1 | c.1020G>A p.Q340= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- IGLV8OR8-1 | n.235G>A | RNA (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- TRPM1 | c.724+1004C>A | Intron (SNP) | VAF 3/28 reads (11%) | catalogued as COSV99856045; called by muse, mutect2
